Somatic mutation profile of tumor specimen MP2PRT-PATWWA-TMP1-A (aliquot MP2PRT-PATWWA-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATWWA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,205 days).
Specimen MP2PRT-PATWWA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70d43b82-1e81-4ce2-bc1e-01f72aa2f4bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATWWA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATWWA-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/207cb599-05df-4f6c-9b6b-4fe1f1f24924

The open-access MAF lists 61 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 16, Nonsense Mutation 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.*22C>G | 3'UTR (SNP) | VAF 40/199 reads (20%) | catalogued as rs104894362, CM070970, COSV55666258, COSV56095155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.3521C>T p.T1174M | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs751624906, COSV55794163; called by muse, mutect2, varscan2
- ADCY8 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 198/405 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53909037; called by muse, mutect2, varscan2
- ARL13B | c.1183G>A p.E395K (on ENST00000394222 / NM_001174150.2; = p.E288K on NM_144996.4) | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV100115736; called by muse, mutect2, varscan2
- CCDC77 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 15/231 reads (6%) | catalogued as rs893823611; called by muse, mutect2
- FHOD1 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 90/355 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV50765363; called by muse, mutect2, varscan2
- GLCCI1 | c.1617C>G p.I539M | Missense Mutation (SNP) | VAF 150/308 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV56206193, COSV99780710; called by muse, mutect2, varscan2
- LINGO2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs781520934, COSV58057149; called by muse, mutect2, varscan2
- MMP16 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54149127; called by muse, mutect2, varscan2
- OR2AG2 | c.798C>A p.H266Q | Missense Mutation (SNP) | VAF 218/446 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as COSV58455638; called by muse, mutect2, varscan2
- PCED1B | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1036994877; called by muse, mutect2, varscan2
- TAAR8 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 65/389 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1433950837, COSV51585633; called by muse, mutect2, varscan2
- TMCC2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 293/622 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs752001776, COSV58004319; called by muse, mutect2, varscan2
- XAGE5 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 127/213 reads (60%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as rs782286603, COSV100657801; called by muse, mutect2, varscan2
- ZNF697 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.097); catalogued as rs1211017361; called by muse, mutect2, varscan2
- ATG9B | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 237/494 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- ATP8A2 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 44/366 reads (12%) | called by muse, mutect2, varscan2
- BTAF1 | c.3838C>A p.L1280I | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1F | c.1179G>C p.E393D | Missense Mutation (SNP) | VAF 349/366 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- CD80 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.092); called by muse, mutect2
- FSIP2 | c.15730G>A p.E5244K | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); called by muse, mutect2
- IGHV3-64 | chr14:106657717 ACTGTGTCTCTC>TTCCGGGG | Missense Mutation (DEL) | VAF 38/133 reads (29%) | called by pindel, varscan2*
- KIR3DL3 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LYN | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 194/411 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LYPLAL1 | c.557G>C p.W186S | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGED1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 167/300 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OR1N1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 109/441 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PLB1 | c.4131C>G p.N1377K | Missense Mutation (SNP) | VAF 106/519 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM8 | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 94/635 reads (15%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAPGEF5 | c.886G>C p.E296Q (on ENST00000401957 / NM_001367602.2; = p.E599Q on NM_012294.5) | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RASSF8 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- RELB | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 264/538 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC2A10 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 160/401 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SPATA5 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.121); called by muse, varscan2
- TDRD15 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- TDRD15 | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 92/197 reads (47%) | called by muse, mutect2, varscan2
- TDRD15 | c.2390C>G p.S797C | Missense Mutation (SNP) | VAF 160/334 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TDRD15 | c.2765C>T p.S922L | Missense Mutation (SNP) | VAF 115/263 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TDRD15 | c.3191C>T p.S1064L | Missense Mutation (SNP) | VAF 126/270 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TMEM74 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 153/349 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- TTC33 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 114/430 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL5 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TXNDC9 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZG16 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 25/467 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); called by muse, mutect2
- BAIAP2L1 | c.1020G>A p.K340= | Silent (SNP) | VAF 195/431 reads (45%) | catalogued as rs952577457, COSV50058308; called by muse, mutect2, varscan2
- ELAPOR2 | c.2629C>T p.L877= (on ENST00000450689 / NM_001142749.3; = p.L710= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 73/416 reads (18%) | catalogued as rs754257028; called by muse, mutect2, varscan2
- F13B | c.600C>T p.Y200= | Silent (SNP) | VAF 124/302 reads (41%) | catalogued as rs544793047, COSV66372650; called by muse, mutect2, varscan2
- GJA8 | c.189C>T p.N63= | Silent (SNP) | VAF 116/456 reads (25%) | catalogued as rs962664876, COSV53787992; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1713G>A p.E571= | Silent (SNP) | VAF 46/350 reads (13%) | catalogued as rs1201245418; called by mutect2, varscan2
- ITGA2 | c.2031C>G p.L677= | Silent (SNP) | VAF 65/386 reads (17%) | catalogued as COSV56856047; called by muse, mutect2, varscan2
- KDM4B | c.2667C>T p.L889= | Silent (SNP) | VAF 97/586 reads (17%) | catalogued as COSV99345884; called by muse, mutect2, varscan2
- MOGAT3 | c.660G>A p.L220= | Silent (SNP) | VAF 46/336 reads (14%) | called by muse, mutect2, varscan2
- NEU4 | c.48G>A p.E16= (on ENST00000391969 / NM_001167602.3; = p.E28= on NM_080741.4) | Silent (SNP) | VAF 106/600 reads (18%) | catalogued as COSV57992408; called by muse, varscan2
- OASL | c.699C>G p.L233= | Silent (SNP) | VAF 50/282 reads (18%) | catalogued as rs1004671711, COSV57477252; called by muse, varscan2
- PKD1L3 | c.3276C>G p.L1092= | Silent (SNP) | VAF 55/422 reads (13%) | called by muse, mutect2, varscan2
- POLR2B | c.3417C>A p.G1139= | Silent (SNP) | VAF 136/263 reads (52%) | catalogued as COSV99825457; called by muse, mutect2, varscan2
- PSG3 | c.846C>A p.V282= | Silent (SNP) | VAF 133/586 reads (23%) | called by muse, mutect2, varscan2
- PSMB9 | c.582C>T p.Y194= | Silent (SNP) | VAF 114/464 reads (25%) | called by muse, mutect2, varscan2
- PTPRU | c.1395C>T p.L465= | Silent (SNP) | VAF 78/307 reads (25%) | called by muse, mutect2, varscan2
- RGS7 | c.1233G>A p.V411= | Silent (SNP) | VAF 143/319 reads (45%) | called by muse, mutect2, varscan2
- SF1 | c.*312_*319del | 3'UTR (DEL) | VAF 53/205 reads (26%) | called by mutect2, pindel, varscan2
